Somatic mutation profile of tumor specimen TCGA-39-5011-01A (aliquot TCGA-39-5011-01A-01D-1441-08) from TCGA case TCGA-39-5011, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.6 years (25,788 days).
Specimen TCGA-39-5011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d1c4761-ae01-4ad4-9b40-b317e905ae66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5011-11A (Solid Tissue Normal), aliquot TCGA-39-5011-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce2235e2-77e5-4b26-85f2-685bb581aded

The open-access MAF lists 691 somatic variants for this specimen: 539 protein-altering or splice-affecting, 144 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 467, Silent 144, Nonsense Mutation 38, Splice Site 16, Frame Shift Del 8, Frame Shift Ins 6, Intron 3, Splice Region 3, RNA 2, In Frame Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262468, COSV50595028; called by muse, mutect2, varscan2
- TP53 | c.581T>A p.L194H | Missense Mutation (SNP) | VAF 38/100 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4025G>T p.R1342L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101036677; called by muse, mutect2, varscan2
- ABCA10 | c.1730G>T p.R577L | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs546114873, COSV99288134; called by muse, mutect2, varscan2
- ABCA6 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as COSV52644760, COSV99446062; called by muse, mutect2
- ABCB1 | c.3163G>T p.G1055* | Nonsense Mutation (SNP) | VAF 49/122 reads (40%) | catalogued as COSV55953603; called by muse, mutect2, varscan2
- ABCB1 | c.3162G>T p.Q1054H | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV99712435; called by muse, mutect2, varscan2
- ABCB10 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100747877; called by muse, mutect2, varscan2
- ABCB5 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765461658, COSV99327770; called by muse, mutect2, varscan2
- ABCB5 | c.3715G>T p.E1239* (on ENST00000404938 / NM_001163941.2; = p.E794* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV99327773; called by muse, mutect2, varscan2
- ABCC11 | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100750570, COSV100750611; called by muse, mutect2, varscan2
- ABCG2 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV99418720; called by muse, mutect2, varscan2
- AC011448.1 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.445); catalogued as COSV99388954; called by muse, mutect2
- AC136428.1 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 39/356 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV101434955; called by muse, mutect2, varscan2
- ACACB | c.3673C>T p.R1225W | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs759403747, COSV100622529; called by muse, mutect2
- ACAD10 | c.237G>T p.L79F | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100563931; called by muse, mutect2, varscan2
- ACTR3 | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99603448; called by muse, mutect2, varscan2
- ACTRT2 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); catalogued as COSV101007529; called by muse, mutect2, varscan2
- ADAMTS12 | c.2449C>A p.L817I | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as COSV100710462; called by muse, mutect2, varscan2
- ADAMTS12 | c.1918A>T p.I640L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs889053112, COSV100710463; called by muse, mutect2, varscan2
- ADAMTS15 | c.2318G>T p.R773L | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.208); catalogued as COSV100143190; called by muse, mutect2, varscan2
- ADAMTS16 | c.3092C>A p.T1031N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.139); catalogued as COSV56977629; called by muse, mutect2, varscan2
- ADGRB3 | c.3103-2A>T p.X1035_splice | Splice Site (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99484137; called by muse, mutect2, varscan2
- ADGRG4 | c.4534C>A p.Q1512K | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99794805; called by muse, mutect2, varscan2
- ADGRG7 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99840693; called by muse, varscan2
- ADGRL3 | c.1895C>A p.S632Y (on ENST00000506720 / NM_001322402.2; = p.S564Y on NM_015236.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100800325; called by muse, mutect2, varscan2
- ADGRL3 | c.3010C>A p.Q1004K (on ENST00000506720 / NM_001322402.2; = p.Q936K on NM_015236.6) | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.602); catalogued as COSV72229409, COSV72231556; called by muse, mutect2
- ADIPOQ | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100292102; called by muse, mutect2
- AGFG1 | c.814+1G>T p.X272_splice | Splice Site (SNP) | VAF 38/166 reads (23%) | catalogued as COSV100028490; called by muse, mutect2, varscan2
- AHNAK2 | c.2354C>G p.A785G | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.03); catalogued as COSV100316351, COSV100316473; called by muse, mutect2, varscan2
- AK9 | c.332-2A>T p.X111_splice | Splice Site (SNP) | VAF 48/163 reads (29%) | catalogued as COSV99572412; called by muse, mutect2, varscan2
- AKAP12 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.363); catalogued as COSV99482764; called by muse, mutect2, varscan2
- AL121899.2 | c.931del p.R311Gfs*2 | Frame Shift Del (DEL) | VAF 70/232 reads (30%) | catalogued as COSV67350046; called by mutect2, pindel, varscan2
- AL592490.1 | c.1293A>G p.I431M | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV69426687; called by muse, mutect2, varscan2
- ALMS1 | c.1084G>C p.A362P | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100041622; called by muse, mutect2, varscan2
- ALPI | c.824C>A p.A275E | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV99785749; called by muse, mutect2, varscan2
- ANAPC1 | c.748A>T p.N250Y | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV100594587; called by muse, mutect2, varscan2
- ANKFN1 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.069); catalogued as COSV100593262; called by muse, mutect2, varscan2
- ANKRD17 | c.4555G>C p.E1519Q | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV100428761, COSV58214758, COSV58219516; called by muse, mutect2, varscan2
- ANKRD2 | c.933G>T p.L311= | Splice Region (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100080761; called by muse, mutect2
- ANKRD34B | c.1067G>T p.R356I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV100103412; called by muse, mutect2, varscan2
- ANO4 | c.495G>T p.L165F (on ENST00000392977 / NM_001286615.2; = p.L130F on NM_178826.4) | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100152325; called by muse, mutect2, varscan2
- APBB1IP | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.473); catalogued as COSV63302351, COSV63304073, COSV63305035; called by muse, mutect2, varscan2
- APOB | c.2170G>T p.G724C | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143425834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP12B | c.355C>A p.L119I (on ENST00000621682; = p.L131I on NM_001102467.2) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.412); catalogued as COSV101315849; called by muse, mutect2
- ARHGAP33 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.083); catalogued as COSV50122375, COSV99137722; called by muse, mutect2, varscan2
- ARHGAP4 | c.1066G>T p.D356Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV100603913; called by muse, mutect2, varscan2
- ARMCX1 | c.422G>T p.S141I | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV100863147, COSV100863165; called by muse, mutect2, varscan2
- ASTN1 | c.3765C>A p.Y1255* | Nonsense Mutation (SNP) | VAF 19/141 reads (13%) | catalogued as COSV100705757; called by muse, mutect2, varscan2
- ASXL3 | c.2970C>A p.N990K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV99323942; called by muse, mutect2
- ASXL3 | c.3387G>T p.L1129F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); catalogued as COSV52461333, COSV99323944; called by muse, mutect2, varscan2
- ATG16L1 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100731277, COSV100731443; called by muse, mutect2
- ATP10B | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.652); catalogued as COSV100514406; called by muse, mutect2, varscan2
- ATP1A4 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 27/117 reads (23%) | catalogued as COSV63625482; called by muse, mutect2, varscan2
- ATP4A | c.653C>A p.A218E | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs769990049, COSV52866484, COSV99382287; called by muse, mutect2, varscan2
- ATP4A | c.103_104insT p.G35Vfs*19 | Frame Shift Ins (INS) | VAF 49/301 reads (16%) | catalogued as COSV99382291; called by mutect2, pindel, varscan2
- ATP7A | c.1532G>T p.R511M | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV100430472; called by muse, mutect2, varscan2
- AVPR1A | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100146797; called by muse, mutect2, varscan2
- BAZ2B | c.2311G>T p.A771S | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as COSV100600474; called by muse, mutect2, varscan2
- BCHE | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100012263; called by muse, mutect2, varscan2
- BCOR | c.5086G>A p.E1696K (on ENST00000378444 / NM_001123385.2; = p.E1662K on NM_017745.6) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100653037; called by muse, varscan2
- BORCS6 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV101197991; called by muse, mutect2, varscan2
- BRWD1 | c.2368G>T p.V790L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100313038; called by muse, mutect2, varscan2
- C10orf53 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV100934854; called by muse, mutect2, varscan2
- CACNA1E | c.1101C>A p.F367L | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100701507; called by muse, mutect2
- CARNMT1 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100961667; called by muse, mutect2, varscan2
- CASS4 | c.755A>T p.K252M | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV100824580; called by muse, mutect2, varscan2
- CATSPERB | c.1262A>C p.H421P | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99830979; called by muse, mutect2, varscan2
- CBL | c.1211G>T p.C404F | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50629989, COSV99875779; called by muse, mutect2, varscan2
- CBLL1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1182064552, COSV99755493; called by muse, mutect2, varscan2
- CCDC113 | c.355A>T p.R119W | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99540749; called by muse, mutect2, varscan2
- CCER1 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as COSV100726964; called by muse, mutect2, varscan2
- CCL7 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99565491; called by muse, mutect2, varscan2
- CCNG2 | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs760060047, COSV100313088; called by muse, mutect2, varscan2
- CCT7 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99240588; called by muse, mutect2, varscan2
- CCT8L2 | c.1507G>T p.G503* | Nonsense Mutation (SNP) | VAF 40/200 reads (20%) | catalogued as COSV63462245, COSV63463775; called by muse, mutect2, varscan2
- CD180 | c.1587C>A p.H529Q | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99842146; called by muse, mutect2, varscan2
- CD300A | c.274A>T p.N92Y | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100177865; called by muse, mutect2, varscan2
- CD3G | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99416531; called by muse, mutect2, varscan2
- CD5L | c.817T>A p.W273R | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941018; called by muse, mutect2
- CDH10 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV100050548, COSV52573772; called by muse, mutect2, varscan2
- CDH19 | c.1190C>A p.P397Q | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100051167; called by muse, mutect2, varscan2
- CDH23 | c.2807T>C p.M936T | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1178387453, COSV99819579; called by muse, mutect2, varscan2
- CELF1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100136754, COSV60111645; called by muse, mutect2, varscan2
- CELSR2 | c.6712C>T p.P2238S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV99603314; called by muse, mutect2, varscan2
- CENPF | c.4380G>T p.L1460F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.94); catalogued as COSV100871584; called by muse, mutect2
- CEP72 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 50/155 reads (32%) | catalogued as COSV99374588; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.624); catalogued as COSV100291826; called by muse, mutect2, varscan2
- CHRNA6 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV52378479, COSV99373114; called by muse, mutect2, varscan2
- CHRNG | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99285601; called by muse, mutect2, varscan2
- CITED2 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV100863097; called by muse, mutect2, varscan2
- CLCA4 | c.1904C>A p.S635* | Nonsense Mutation (SNP) | VAF 33/210 reads (16%) | catalogued as COSV55366558; called by muse, mutect2, varscan2
- CLCN4 | c.1786G>T p.A596S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV101073717; called by muse, mutect2, varscan2
- CLSTN2 | c.2781G>T p.E927D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101515595, COSV71723644; called by muse, mutect2
- CNTN6 | c.2828G>T p.R943L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100610346, COSV100611951; called by muse, mutect2, varscan2
- COG1 | c.1227G>C p.K409N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV100245219; called by muse, mutect2, varscan2
- COL16A1 | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.015); catalogued as COSV99593804; called by muse, mutect2, varscan2
- COL24A1 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.19); catalogued as COSV100993054; called by muse, mutect2, varscan2
- COL6A6 | c.1240A>T p.T414S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV100650002, COSV100650601; called by muse, mutect2, varscan2
- COL8A1 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657350; called by muse, mutect2, varscan2
- CPLX4 | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV100231287; called by muse, mutect2, varscan2
- CPN1 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV64942243; called by muse, mutect2, varscan2
- CREB3L1 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99914880; called by muse, mutect2
- CRHR2 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100529808, COSV59267598; called by muse, mutect2, varscan2
- CRISP3 | c.260C>A p.P87H (on ENST00000371159 / NM_001368123.1; = p.P69H on NM_006061.4) | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV53822174; called by muse, mutect2, varscan2
- CRISP3 | c.128C>A p.A43D (on ENST00000371159 / NM_001368123.1; = p.A25D on NM_006061.4) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99538749; called by muse, mutect2, varscan2
- CRTAM | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV99911854; called by muse, mutect2, varscan2
- CSMD1 | c.8334G>T p.Q2778H (on ENST00000520002; = p.Q2777H on NM_033225.6) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs376117864; called by muse, varscan2
- CSMD2 | c.5944C>A p.P1982T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53911997, COSV53918677; called by muse, mutect2, varscan2
- CSMD3 | c.11071G>A p.G3691R (on ENST00000297405 / NM_001363185.1; = p.G3522R on NM_052900.3) | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV52195616; called by muse, mutect2
- CSMD3 | c.2293G>T p.D765Y (on ENST00000297405 / NM_001363185.1; = p.D661Y on NM_052900.3) | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99828383; called by muse, mutect2, varscan2
- CSN3 | c.518C>A p.T173N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.518); catalogued as COSV100515279; called by muse, mutect2
- CSPG4 | c.4571G>T p.R1524L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs140387476, COSV100413583; called by muse, mutect2, varscan2
- CTCFL | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99712303; called by muse, mutect2, varscan2
- CTNND2 | c.3042C>A p.N1014K | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100473497; called by muse, mutect2, varscan2
- CUX1 | c.2979G>C p.Q993H | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554520536, COSV99470846; called by muse, mutect2, varscan2
- CYP4F8 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs1282355357, COSV57855755; called by muse, mutect2, varscan2
- CYP8B1 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100296068; called by muse, mutect2, varscan2
- DACH1 | c.925G>T p.V309F | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV100497834; called by muse, mutect2, varscan2
- DCDC1 | c.5174G>T p.R1725L (on ENST00000597505 / NM_001367979.1; = p.R832L on NM_020869.3) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV100360347; called by muse, mutect2
- DCLRE1B | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100849769; called by muse, mutect2, varscan2
- DENND2A | c.2123C>A p.P708Q | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99325715; called by muse, mutect2, varscan2
- DENND4C | c.5200G>T p.V1734L (on ENST00000434457 / NM_001330640.2; = p.V1685L on NM_017925.7) | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV100727360; called by muse, mutect2, varscan2
- DHTKD1 | c.1750G>C p.A584P | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.317); catalogued as COSV99536197; called by muse, mutect2, varscan2
- DHX57 | c.573-1G>T p.X191_splice | Splice Site (SNP) | VAF 16/82 reads (20%) | catalogued as COSV54893358; called by muse, mutect2, varscan2
- DICER1 | c.5418G>T p.K1806N | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100601882; called by muse, mutect2, varscan2
- DIDO1 | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV56626547, COSV99825179; called by muse, mutect2
- DMD | c.4258C>T p.H1420Y | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1475038240, COSV100818666; called by muse, mutect2, varscan2
- DMXL1 | c.4948G>T p.A1650S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.388); catalogued as COSV100223541; called by muse, mutect2, varscan2
- DNAH1 | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV101325061; called by muse, mutect2, varscan2
- DNAH3 | c.6613C>A p.R2205S | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54508265, COSV54528865; called by muse, mutect2, varscan2
- DNAI4 | c.1462G>T p.V488L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100925262; called by muse, mutect2, varscan2
- DOCK10 | c.3793G>T p.D1265Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99288296; called by muse, mutect2, varscan2
- DPYSL4 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.097); catalogued as COSV100633868; called by muse, mutect2, varscan2
- DRAXIN | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.233); catalogued as COSV99610607; called by muse, mutect2
- DRGX | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as COSV100938309; called by muse, mutect2, varscan2
- DSCAML1 | c.417C>A p.N139K (on ENST00000321322; = p.N79K on NM_020693.4) | Missense Mutation (SNP) | VAF 124/381 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100355146, COSV58400300; called by muse, mutect2, varscan2
- DYSF | c.3787G>T p.G1263C | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99245266; called by muse, mutect2
- DYSF | c.3935C>A p.P1312H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1012560132, COSV99245273; called by muse, mutect2
- EBF1 | c.1411G>T p.V471L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.019); catalogued as COSV100565435, COSV100565559; called by muse, mutect2, varscan2
- ECT2L | c.819T>A p.H273Q | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100871809; called by muse, mutect2, varscan2
- EEA1 | c.3565G>C p.E1189Q | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV59282263, COSV59286448; called by muse, mutect2, varscan2
- EIF3M | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100024915; called by muse, mutect2, varscan2
- ELOA | c.982_984del p.K328del | In Frame Del (DEL) | VAF 9/77 reads (12%) | catalogued as rs761845669; called by mutect2, pindel, varscan2
- ELSPBP1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353538; called by muse, mutect2, varscan2
- ENPP2 | c.1356G>T p.W452C (on ENST00000075322 / NM_001040092.3; = p.W504C on NM_006209.5) | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99307806, COSV99309468; called by muse, mutect2
- ENPP3 | c.1632G>T p.K544N | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100716913; called by muse, mutect2
- ERBB4 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53560409, COSV99618835; called by muse, mutect2, varscan2
- EREG | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99791661; called by muse, mutect2, varscan2
- ESRRB | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV55062957, COSV99834957; called by muse, mutect2, varscan2
- ETFB | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.143); catalogued as COSV100495565; called by muse, mutect2, varscan2
- EXOSC2 | c.498A>G p.L166= | Splice Region (SNP) | VAF 46/94 reads (49%) | catalogued as COSV100964240; called by muse, mutect2, varscan2
- EYA4 | c.1181C>A p.T394N (on ENST00000531901 / NM_001301013.1; = p.T388N on NM_004100.5) | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100765407; called by muse, mutect2
- F5 | c.5439C>A p.Y1813* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV100888993; called by muse, mutect2, varscan2
- FAM217B | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100674453; called by muse, mutect2, varscan2
- FAM47C | c.185G>C p.C62S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV100792383; called by muse, mutect2, varscan2
- FAM78B | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100597430; called by muse, mutect2, varscan2
- FAT3 | c.960G>T p.W320C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.823); catalogued as COSV99963365; called by muse, mutect2
- FAT3 | c.7828A>T p.R2610W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99963367; called by muse, mutect2
- FBXL7 | c.411C>G p.C137W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100309339, COSV61641858; called by muse, mutect2, varscan2
- FCER2 | c.927C>A p.D309E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV100689523; called by muse, mutect2, varscan2
- FCRL4 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV99619444; called by muse, mutect2, varscan2
- FCRLB | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100396114; called by muse, mutect2, varscan2
- FER1L6 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101205591; called by muse, mutect2, varscan2
- FGF5 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.272); catalogued as rs374779310; called by muse, mutect2, varscan2
- FGF9 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101210944; called by muse, mutect2, varscan2
- FLG2 | c.3750C>A p.S1250R | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101165687; called by muse, mutect2
- FMR1NB | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.351); catalogued as COSV100975499; called by muse, mutect2, varscan2
- FOXL1 | c.927C>A p.N309K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV100206140; called by muse, mutect2, varscan2
- FOXP2 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 103/177 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV100646371; called by muse, mutect2, varscan2
- FURIN | c.372+1G>T p.X124_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99184629; called by muse, mutect2, varscan2
- FXYD6 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52804636, COSV99502414; called by muse, mutect2, varscan2
- FYCO1 | c.3835G>T p.V1279L | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV99945327; called by muse, mutect2, varscan2
- GABRG3 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.948); catalogued as COSV61509071; called by muse, mutect2, varscan2
- GAD1 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.028); catalogued as rs886412887, COSV100713779; called by muse, mutect2, varscan2
- GANAB | c.1908G>T p.L636F | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV100647907; called by muse, mutect2, varscan2
- GATA2 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100351063; called by muse, mutect2, varscan2
- GATA3 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100650878, COSV60520464; called by muse, mutect2, varscan2
- GC | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99909522; called by muse, mutect2, varscan2
- GDPD4 | c.269G>T p.W90L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100265136; called by muse, mutect2, varscan2
- GGN | c.1819C>G p.L607V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99287364; called by muse, mutect2, varscan2
- GHR | c.1810C>A p.P604T | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100050125; called by muse, mutect2, varscan2
- GIMAP2 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99785259; called by muse, mutect2, varscan2
- GON4L | c.1372A>G p.R458G | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV99673748; called by muse, mutect2, varscan2
- GPA33 | c.828-1G>T p.X276_splice | Splice Site (SNP) | VAF 11/138 reads (8%) | catalogued as COSV100900959; called by muse, mutect2
- GPALPP1 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100689161; called by muse, mutect2, varscan2
- GPR158 | c.2478C>A p.D826E | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs538576018, COSV99059284; called by muse, mutect2, varscan2
- GPR183 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs375590153; called by muse, mutect2, varscan2
- GPR26 | c.982C>A p.H328N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs978265298, COSV99500793; called by muse, mutect2, varscan2
- GPRASP2 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.112); catalogued as COSV100176619; called by muse, mutect2, varscan2
- GPRIN3 | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.463); catalogued as COSV100311041, COSV60885160; called by muse, mutect2, varscan2
- GRID2 | c.2456C>T p.T819I | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV99938691; called by muse, mutect2, varscan2
- GRIK4 | c.883C>A p.H295N | Missense Mutation (SNP) | VAF 124/434 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.234); catalogued as COSV101483521; called by muse, mutect2, varscan2
- GRIN1 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.051); catalogued as COSV100159980; called by muse, mutect2, varscan2
- HELZ2 | c.7799G>T p.R2600L (on ENST00000467148 / NM_001037335.2; = p.R2031L on NM_033405.3) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1297922295, COSV100918768; called by muse, mutect2, varscan2
- HKDC1 | c.2296C>T p.L766F | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1034371933, COSV100664401, COSV100664426; called by muse, mutect2, varscan2
- HLA-DRA | c.702del p.T235Pfs*30 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | catalogued as COSV100895077; called by mutect2, pindel
- HNRNPR | c.1075A>C p.K359Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.39); catalogued as COSV100164378; called by muse, mutect2, varscan2
- HPN | c.455-2A>T p.X152_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99384935; called by muse, mutect2
- HPRT1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as COSV100053104; called by muse, mutect2, varscan2
- HRH1 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101229046; called by muse, mutect2, varscan2
- HTR1A | c.444G>T p.R148S | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100108987; called by muse, mutect2, varscan2
- HTR3D | c.1000G>T p.A334S (on ENST00000382489 / NM_001163646.2; = p.A159S on NM_182537.3) | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.193); catalogued as COSV100487950; called by muse, mutect2, varscan2
- HYDIN | c.4924C>A p.L1642I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99992279; called by mutect2, varscan2
- IBTK | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100090259; called by muse, mutect2, varscan2
- IFIT1 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100878684; called by muse, mutect2, varscan2
- IGHMBP2 | c.2164A>T p.S722C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV99661923; called by muse, mutect2, varscan2
- IKZF2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.146); catalogued as COSV100563346; called by muse, mutect2, varscan2
- IL16 | c.2177G>A p.S726N (on ENST00000302987 / NM_172217.5; = p.S25N on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV100267214; called by muse, mutect2, varscan2
- INHA | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as COSV54715023, COSV99216430; called by muse, mutect2, varscan2
- INPPL1 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); catalogued as rs371380700; called by muse, mutect2, varscan2
- IRF2 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101165787; called by muse, mutect2, varscan2
- KCNA4 | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV60255571; called by muse, mutect2, varscan2
- KCNA4 | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100068713; called by muse, mutect2, varscan2
- KCNH8 | c.2455G>A p.D819N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100109007; called by muse, mutect2, varscan2
- KCNIP3 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV99733816; called by muse, mutect2, varscan2
- KCNJ2 | c.570C>A p.N190K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99696265; called by muse, mutect2, varscan2
- KCNJ8 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV53716118, COSV99557432; called by muse, mutect2, varscan2
- KCNU1 | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV101299033; called by muse, mutect2, varscan2
- KCTD16 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.93); catalogued as COSV101568754; called by muse, mutect2, varscan2
- KDM7A | c.550C>A p.R184S | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV99134070; called by muse, mutect2, varscan2
- KHDRBS2 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55459889, COSV55478164; called by muse, mutect2, varscan2
- KIAA1549L | c.4261C>A p.P1421T (on ENST00000321505; = p.P1718T on NM_012194.3) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100381058; called by muse, mutect2, varscan2
- KIF18A | c.1148A>T p.E383V | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99588425; called by muse, mutect2
- KIF3C | c.2282G>C p.R761T | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); catalogued as COSV53102369, COSV99267165; called by muse, mutect2, varscan2
- KIF5A | c.1716+1G>T p.X572_splice | Splice Site (SNP) | VAF 28/145 reads (19%) | catalogued as COSV99672630; called by muse, mutect2, varscan2
- KIFAP3 | c.2248G>T p.V750F | Missense Mutation (SNP) | VAF 19/345 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as rs1221985548, COSV100846804; called by muse, mutect2
- KLK1 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.435); catalogued as COSV100032596; called by muse, mutect2, varscan2
- KLK4 | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100133568, COSV60676924; called by muse, mutect2, varscan2
- KMT2D | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as COSV99978754; called by muse, mutect2, varscan2
- KRT31 | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.503); catalogued as COSV99289487; called by muse, mutect2
- KRTAP19-4 | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100478407; called by muse, mutect2, varscan2
- KRTAP26-1 | c.213T>A p.C71* | Nonsense Mutation (SNP) | VAF 70/233 reads (30%) | catalogued as COSV100860383; called by muse, varscan2
- KRTAP9-8 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as COSV99565776; called by muse, mutect2, varscan2
- LAMA4 | c.2448G>T p.Q816H (on ENST00000230538 / NM_001105206.3; = p.Q809H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100037870; called by muse, mutect2, varscan2
- LAMB1 | c.502T>A p.Y168N | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV99740209; called by muse, mutect2, varscan2
- LCK | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100287504; called by muse, mutect2, varscan2
- LILRA4 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52493754; called by muse, mutect2, varscan2
- LMBRD1 | c.1149+1G>A p.X383_splice (on ENST00000649011; = p.X361_splice on NM_018368.4) | Splice Site (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100992483; called by muse, mutect2, varscan2
- LMOD2 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.335); catalogued as COSV101505424, COSV71755602; called by muse, mutect2, varscan2
- LRFN2 | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV100599248, COSV57828413; called by muse, mutect2, varscan2
- LRFN5 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99982923; called by muse, mutect2, varscan2
- LRP1 | c.9517A>T p.I3173F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99675015; called by muse, mutect2, varscan2
- LRRC15 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV100752598; called by muse, varscan2
- LRRC15 | c.775C>A p.Q259K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV100752599; called by muse, varscan2
- LRRC32 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99476758; called by muse, mutect2, varscan2
- LRRIQ1 | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101277699, COSV67813365; called by muse, mutect2, varscan2
- LRRTM3 | c.590C>G p.A197G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV100791538; called by muse, mutect2, varscan2
- LY75 | c.1700G>C p.G567A | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55112780; called by muse, mutect2, varscan2
- MAGEA1 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV100756621; called by muse, mutect2, varscan2
- MAGEB6 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66872504, COSV66872841; called by muse, mutect2, varscan2
- MAGEC1 | c.90C>A p.D30E | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV99595186; called by muse, mutect2, varscan2
- MAP3K1 | c.519G>T p.L173F | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101266412; called by muse, mutect2, varscan2
- MAST2 | c.3604C>T p.R1202W | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100787945; called by muse, mutect2, varscan2
- MEP1A | c.186+1G>T p.X62_splice | Splice Site (SNP) | VAF 17/121 reads (14%) | catalogued as rs747163347, COSV100042476; called by muse, mutect2, varscan2
- METTL18 | c.61A>G p.R21G | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99609526; called by muse, mutect2, varscan2
- MFAP3L | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.705); catalogued as COSV100852646; called by muse, mutect2, varscan2
- MGAM | c.4735C>A p.P1579T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV101527415; called by muse, mutect2, varscan2
- MITF | c.1412G>C p.G471A (on ENST00000448226 / NM_006722.3; = p.G371A on NM_000248.4) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs200766286, COSV100096649, COSV58830467; called by muse, mutect2, varscan2
- MLXIPL | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100515223, COSV57668953; called by muse, varscan2
- MMP16 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99686724; called by muse, mutect2, varscan2
- MROH2B | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.055); catalogued as COSV101270591; called by muse, mutect2, varscan2
- MSGN1 | c.522C>A p.Y174* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as COSV99808702; called by muse, mutect2, varscan2
- MUC3A | c.8009C>A p.T2670K | Missense Mutation (SNP) | VAF 245/1261 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100114198; called by muse, mutect2, varscan2
- MYH13 | c.5380G>T p.V1794L | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV99352899; called by muse, mutect2, varscan2
- MYH6 | c.2387G>C p.G796A | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100676379; called by muse, mutect2, varscan2
- MYLK | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV100658665; called by muse, mutect2
- MYOCD | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV100590363; called by muse, mutect2
- MYOM2 | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs963720379, COSV100037007; called by muse, mutect2, varscan2
- NADSYN1 | c.1727A>C p.E576A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100034510; called by muse, mutect2
- NALCN | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.383); catalogued as rs1385150576, COSV99213624; called by muse, mutect2
- NALCN | c.1712G>T p.W571L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99213625; called by muse, mutect2
- NBAS | c.2581G>T p.D861Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99868018; called by muse, mutect2
- NCAPH | c.1328A>C p.D443A | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as COSV99545643; called by muse, mutect2, varscan2
- NCKAP5 | c.2027G>T p.G676V | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100490694, COSV99048456; called by muse, mutect2, varscan2
- NCKAP5 | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490698; called by muse, mutect2, varscan2
- NCKAP5L | c.2441G>T p.S814I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258492; called by muse, mutect2, varscan2
- NCOA6 | c.4369C>T p.Q1457* | Nonsense Mutation (SNP) | VAF 22/133 reads (17%) | catalogued as COSV62862026; called by muse, mutect2, varscan2
- NELL2 | c.1833C>A p.H611Q | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100419027; called by muse, mutect2, varscan2
- NETO1 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV55002620; called by muse, mutect2, varscan2
- NEU4 | c.928G>T p.G310C (on ENST00000391969 / NM_001167602.3; = p.G322C on NM_080741.4) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100371889, COSV57990168, COSV57992101; called by muse, mutect2, varscan2
- NFE2 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100380693; called by muse, mutect2, varscan2
- NID2 | c.2484G>C p.E828D | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV99356132; called by muse, mutect2, varscan2
- NLRP1 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 103/281 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV99333347; called by muse, mutect2, varscan2
- NME7 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100890943; called by muse, mutect2
- NMUR2 | c.43C>A p.Q15K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.038); catalogued as COSV99676725; called by muse, mutect2, varscan2
- NOC4L | c.625A>T p.N209Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100222977; called by muse, mutect2, varscan2
- NOS1 | c.2419G>C p.V807L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.999); catalogued as COSV100500229; called by muse, mutect2, varscan2
- NOTCH2 | c.4945C>A p.L1649I | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs769177875, COSV99863203; called by muse, mutect2, varscan2
- NOTCH4 | c.5867T>A p.L1956Q | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1219394249, COSV100900487; called by muse, mutect2, varscan2
- NOVA1 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV99946837; called by muse, mutect2, varscan2
- NPAS3 | c.1927G>T p.A643S (on ENST00000356141 / NM_001164749.2; = p.A611S on NM_022123.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV100639881; called by muse, mutect2, varscan2
- NRCAM | c.2299T>A p.W767R (on ENST00000379028 / NM_001371124.1; = p.W751R on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100694444; called by muse, mutect2, varscan2
- NRF1 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV99781647; called by muse, mutect2, varscan2
- NRXN1 | c.487C>A p.R163S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs1338512958, COSV101277085; called by muse, mutect2, varscan2
- NSF | c.1555G>C p.D519H | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as COSV99833729; called by muse, mutect2, varscan2
- NTRK1 | c.934T>G p.S312A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100693198; called by muse, mutect2, varscan2
- NTRK3 | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100712450; called by muse, mutect2, varscan2
- NUF2 | c.10T>G p.L4V | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99616223; called by muse, mutect2, varscan2
- OLFM4 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV54581475; called by muse, mutect2, varscan2
- OPN1SW | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV99975567, COSV99975845; called by muse, mutect2, varscan2
- OPRM1 | c.690G>C p.W230C | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100000727, COSV57687222; called by muse, mutect2, varscan2
- OPRM1 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs200735555, COSV100000763; called by muse, mutect2, varscan2
- OPTC | c.746T>A p.L249Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100921744; called by muse, mutect2, varscan2
- OR10H2 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100008662; called by muse, mutect2, varscan2
- OR10K1 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99193310; called by muse, mutect2, varscan2
- OR10Q1 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV100372186; called by muse, varscan2
- OR13F1 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 84/380 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100594711; called by muse, mutect2, varscan2
- OR2D2 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100203755, COSV55056685; called by muse, mutect2, varscan2
- OR2F1 | c.528C>A p.H176Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231294; called by muse, mutect2, varscan2
- OR2G2 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100189647; called by muse, mutect2, varscan2
- OR2W3 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as rs1365371916, COSV64457182, COSV64457996; called by muse, mutect2, varscan2
- OR4K15 | c.894C>A p.F298L (on ENST00000305051; = p.F274L on NM_001005486.1) | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100521001, COSV59302602; called by muse, mutect2, varscan2
- OR4S2 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs371541216, COSV100412584; called by muse, mutect2, varscan2
- OR52B4 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV101281578; called by muse, mutect2, varscan2
- OR5D14 | c.182T>A p.M61K | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100162240; called by muse, mutect2, varscan2
- OR5I1 | c.64C>A p.R22S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100041282; called by muse, mutect2, varscan2
- OR6M1 | c.767A>C p.Y256S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100484034; called by muse, mutect2, varscan2
- OR7A10 | c.516G>C p.M172I | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV99932398; called by muse, mutect2, varscan2
- OR8B4 | c.602T>A p.V201D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV100635775; called by muse, mutect2, varscan2
- OTOF | c.3229C>T p.Q1077* (on ENST00000272371 / NM_194248.3; = p.Q330* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99716927; called by muse, mutect2, varscan2
- OXSR1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100309235; called by muse, mutect2, varscan2
- P2RX5 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56593192, COSV99835689; called by muse, mutect2, varscan2
- PACS1 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100269706; called by muse, mutect2, varscan2
- PADI3 | c.1574C>A p.T525N | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100968433, COSV64934600; called by muse, mutect2
- PADI6 | c.103T>A p.L35M | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100639905; called by muse, mutect2, varscan2
- PARD3 | c.3802G>T p.G1268C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100631309; called by muse, varscan2
- PARP15 | c.1660G>A p.E554K (on ENST00000464300 / NM_001113523.3; = p.E320K on NM_152615.2) | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1000101516, COSV100117009; called by muse, mutect2, varscan2
- PBX4 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99232051; called by muse, mutect2
- PCDH10 | c.2890C>A p.R964S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV99993199, COSV99994076; called by muse, mutect2, varscan2
- PCDH17 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100931494, COSV64973047; called by muse, mutect2, varscan2
- PCDHB12 | c.1481A>T p.Q494L | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.315); catalogued as COSV99506972; called by muse, mutect2, varscan2
- PCDHB7 | c.2364G>T p.Q788H | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV50759775, COSV99176363; called by muse, mutect2
- PCOLCE2 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV99930462; called by muse, mutect2, varscan2
- PCYT1B | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100770532; called by muse, mutect2, varscan2
- PDE10A | c.1297C>A p.H433N | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV100604732; called by muse, mutect2, varscan2
- PDE6A | c.1074C>A p.N358K | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV99677998; called by muse, mutect2, varscan2
- PDGFD | c.380G>C p.R127T | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.265); catalogued as COSV100158330; called by muse, mutect2, varscan2
- PDILT | c.1094G>C p.S365T | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV100199184; called by muse, mutect2, varscan2
- PDZRN4 | c.701T>C p.L234S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV68418004; called by muse, mutect2, varscan2
- PGK2 | c.1148G>A p.W383* | Nonsense Mutation (SNP) | VAF 19/233 reads (8%) | catalogued as COSV100505374; called by muse, mutect2
- PHC1 | c.1899A>T p.K633N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV101418539; called by muse, mutect2
- PIAS3 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs782084511, COSV65171784; called by muse, mutect2
- PIK3CG | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV63247420; called by muse, mutect2, varscan2
- PIK3CG | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1415434072, COSV63248798; called by muse, mutect2, varscan2
- PLEKHG7 | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 9/212 reads (4%) | catalogued as COSV101188836, COSV67338128; called by muse, mutect2
- PLXNA4 | c.5439-1G>T p.X1813_splice | Splice Site (SNP) | VAF 29/123 reads (24%) | catalogued as COSV100323153; called by muse, mutect2, varscan2
- POMT1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs549698565, COSV100586194, COSV61224941; called by muse, mutect2, varscan2
- POP1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100855684; called by muse, mutect2, varscan2
- PPP1R21 | c.1988G>T p.R663L (on ENST00000294952 / NM_001135629.3; = p.R652L on NM_152994.5) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs147453938, COSV99681787, COSV99681896; called by muse, mutect2, varscan2
- PPP1R3A | c.2510G>T p.C837F | Missense Mutation (SNP) | VAF 45/468 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as COSV99492270; called by muse, mutect2, varscan2
- PPP1R3C | c.893G>T p.S298I | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV99490881; called by muse, mutect2, varscan2
- PRAMEF2 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV99534989; called by muse, mutect2, varscan2
- PRKDC | c.9749A>G p.N3250S | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV100039098; called by muse, mutect2, varscan2
- PRKG1 | c.983G>T p.C328F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100907190; called by muse, mutect2, varscan2
- PRPF40A | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV101344187; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1695G>T p.Q565H (on ENST00000352766; = p.Q486H on NM_181334.5) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100424073; called by muse, mutect2, varscan2
- PTK2 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 25/470 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV100569752; called by muse, mutect2
- PXDNL | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100682450, COSV62499506; called by muse, mutect2
- RAB11FIP2 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs746180972, COSV100843013; called by muse, mutect2, varscan2
- RANBP17 | c.2747C>T p.T916I | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV101206145; called by muse, mutect2, varscan2
- RB1CC1 | c.3092C>T p.S1031F | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV99208834; called by muse, mutect2, varscan2
- RBM42 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99178052; called by muse, mutect2
- RBP4 | c.327G>T p.W109C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101012241; called by muse, mutect2, varscan2
- REPIN1 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV68291881; called by muse, mutect2
- RFX6 | c.2005G>T p.G669C | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.04); catalogued as COSV100263470; called by muse, mutect2, varscan2
- RGS21 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV101313996; called by muse, mutect2, varscan2
- RHOH | c.573C>G p.F191L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV101110424; called by muse, mutect2
- RNASE8 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1329726505, COSV100373491, COSV57551859; called by muse, mutect2, varscan2
- RNF31 | c.1337G>T p.R446L | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53761398, COSV99395941; called by muse, mutect2, varscan2
- ROS1 | c.5654G>A p.R1885K | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100876669; called by muse, mutect2, varscan2
- RP1L1 | c.6049C>A p.Q2017K | Missense Mutation (SNP) | VAF 92/347 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV101223051; called by muse, mutect2, varscan2
- RP1L1 | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100261761; called by muse, mutect2, varscan2
- RPA1 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99627773; called by muse, mutect2, varscan2
- RPH3A | c.557C>T p.A186V (on ENST00000389385 / NM_001143854.2; = p.A182V on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1279369551, COSV101231784; called by muse, mutect2, varscan2
- RPH3A | c.769G>T p.A257S (on ENST00000389385 / NM_001143854.2; = p.A253S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0.036); catalogued as COSV101231785, COSV66990050; called by muse, mutect2, varscan2
- RPH3A | c.1310T>G p.L437R (on ENST00000389385 / NM_001143854.2; = p.L433R on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101231786; called by muse, mutect2, varscan2
- RPL7A | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs915574810, COSV100034595; called by muse, mutect2
- RPTN | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 141/663 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV100285336; called by muse, mutect2, varscan2
- RTP1 | c.73A>T p.R25W | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1182464970, COSV100398688; called by muse, mutect2, varscan2
- RTTN | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV99731510; called by muse, mutect2, varscan2
- SATL1 | c.590T>C p.L197P (on ENST00000395409; = p.L384P on NM_001012980.2) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100260700; called by muse, mutect2, varscan2
- SAXO1 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as rs1035643925, COSV101000127, COSV65870599; called by muse, mutect2, varscan2
- SCN10A | c.3836C>A p.P1279Q | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771215781, COSV101479288; called by muse, mutect2, varscan2
- SCN10A | c.3715G>C p.E1239Q | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101479289, COSV71860462; called by muse, mutect2, varscan2
- SCYL2 | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs969148437, COSV100675097; called by muse, mutect2, varscan2
- SECISBP2L | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV99960056; called by muse, mutect2, varscan2
- SEMA5A | c.1643C>A p.P548Q | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV101227433, COSV66787210; called by muse, mutect2
- SEMG2 | c.692C>A p.S231* | Nonsense Mutation (SNP) | VAF 38/174 reads (22%) | catalogued as COSV101034002; called by muse, mutect2, varscan2
- SERPINA5 | c.512A>T p.Q171L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100291522; called by muse, mutect2, varscan2
- SERPINA5 | c.983C>G p.T328S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV100291523; called by muse, mutect2, varscan2
- SETBP1 | c.4412A>T p.Q1471L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV99952466; called by muse, mutect2
- SGIP1 | c.876C>A p.D292E | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99390874; called by muse, mutect2, varscan2
- SGIP1 | c.1264G>C p.V422L | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.785); catalogued as COSV99390877; called by muse, mutect2
- SH3TC1 | c.2495C>G p.A832G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV99794571; called by muse, varscan2
- SHD | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101619028; called by muse, mutect2, varscan2
- SIDT1 | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV99333376; called by muse, mutect2, varscan2
- SIPA1L1 | c.1534G>T p.G512C | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100665280; called by muse, mutect2, varscan2
- SIPA1L1 | c.4756G>A p.D1586N | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100665281; called by muse, mutect2, varscan2
- SLC12A3 | c.2052G>C p.Q684H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs751560963, COSV52637940, COSV99343933; called by muse, mutect2, varscan2
- SLC13A1 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99520597; called by muse, mutect2, varscan2
- SLC14A2 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 35/165 reads (21%) | catalogued as COSV54907500, COSV99675242; called by muse, mutect2, varscan2
- SLC37A1 | c.649A>T p.T217S | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100721608; called by muse, mutect2, varscan2
- SLC44A5 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100901467; called by muse, mutect2, varscan2
- SLC4A2 | c.458A>T p.Q153L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.122); catalogued as COSV100055039; called by muse, mutect2, varscan2
- SLC6A15 | c.1453C>A p.P485T | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV99880364; called by muse, mutect2, varscan2
- SLC6A7 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100046065; called by muse, mutect2, varscan2
- SLC9A4 | c.1866G>T p.K622N | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV54832326; called by muse, mutect2, varscan2
- SLF1 | c.2830G>C p.E944Q | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99475700; called by muse, mutect2, varscan2
- SLITRK2 | c.2147A>T p.Q716L | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as COSV100157468; called by muse, mutect2
- SLITRK2 | c.2149G>T p.E717* | Nonsense Mutation (SNP) | VAF 39/167 reads (23%) | catalogued as COSV59426650; called by muse, mutect2
- SMC2 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs1392989465, COSV99658496, COSV99658621; called by muse, mutect2, varscan2
- SMCHD1 | c.3824G>T p.R1275I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55251339; called by muse, mutect2, varscan2
- SNAI2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99194938; called by muse, mutect2, varscan2
- SOCS6 | c.1081G>T p.V361L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV101205684; called by muse, mutect2, varscan2
- SORCS1 | c.3070G>T p.V1024L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV99544313; called by muse, mutect2, varscan2
- SP7 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs775812903, COSV58190799; called by muse, mutect2, varscan2
- SPATA31E1 | c.3619C>A p.H1207N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100350098; called by muse, mutect2
- SPTA1 | c.7240A>C p.N2414H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.99); catalogued as COSV100778961; called by muse, mutect2, varscan2
- SPTB | c.1982C>G p.S661C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV101071942, COSV101072012; called by muse, mutect2, varscan2
- SSBP1 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV99519736; called by muse, mutect2, varscan2
- SSTR3 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100142559, COSV60729346; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | PolyPhen probably damaging (1); catalogued as COSV100602501; called by muse, mutect2, varscan2
- STAB2 | c.4216T>C p.C1406R | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101185729; called by muse, mutect2, varscan2
- STK39 | c.841-2A>T p.X281_splice | Splice Site (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100596345; called by muse, mutect2, varscan2
- STON2 | c.2486A>T p.E829V (on ENST00000649389 / NM_001366849.2; = p.E772V on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99964521; called by muse, mutect2, varscan2
- STON2 | c.2485G>T p.E829* (on ENST00000649389 / NM_001366849.2; = p.E772* on NM_001256430.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/199 reads (20%) | catalogued as COSV99964523; called by muse, mutect2, varscan2
- STYXL2 | c.3434A>T p.Q1145L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as COSV99608771; called by muse, mutect2
- SUCNR1 | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100751715; called by muse, mutect2, varscan2
- SUN5 | c.78G>T p.R26S | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV50064818, COSV99401254; called by muse, mutect2, varscan2
- SYNDIG1L | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV59048164; called by muse, mutect2, varscan2
- SYNE2 | c.19213G>C p.G6405R | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760575138, COSV100647090; called by muse, mutect2, varscan2
- TAB3 | c.1746A>T p.R582S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99915955; called by muse, mutect2, varscan2
- TAF1 | c.2281G>T p.V761L (on ENST00000373790 / NM_138923.4; = p.V782L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as COSV99334977; called by muse, mutect2, varscan2
- TAS1R2 | c.1592-1G>T p.X531_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100946162; called by muse, mutect2, varscan2
- TBC1D32 | c.2246-1G>T p.X749_splice | Splice Site (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99249786; called by muse, mutect2
- TBPL2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1370123558, COSV55972166; called by muse, mutect2, varscan2
- TBX15 | c.1444C>T p.Q482* (on ENST00000369429 / NM_001330677.2; = p.Q376* on NM_152380.3) | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99253791; called by muse, mutect2, varscan2
- TCF20 | c.4427A>T p.Q1476L | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.344); catalogued as COSV100166373; called by muse, mutect2, varscan2
- TDP1 | c.527C>A p.P176Q | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.033); catalogued as COSV100187649; called by muse, mutect2, varscan2
- TEP1 | c.5834G>T p.G1945V | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99401886; called by muse, mutect2, varscan2
- TEP1 | c.5833G>C p.G1945R | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99401887; called by muse, mutect2, varscan2
- TG | c.633C>A p.Y211* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99599675; called by muse, mutect2
- TG | c.5597T>G p.V1866G | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV99599676; called by muse, mutect2, varscan2
- THAP6 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1485446441, COSV100185752; called by muse, mutect2, varscan2
- THSD7A | c.3881C>T p.P1294L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV101439729, COSV69855823; called by muse, mutect2, varscan2
- TLK2 | c.1759C>T p.P587S (on ENST00000326270 / NM_001284333.2; = p.P565S on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV58297982; called by muse, mutect2
- TLR4 | c.819C>A p.D273E (on ENST00000355622 / NM_138554.5; = p.D233E on NM_003266.4) | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100790622; called by muse, varscan2
- TLR4 | c.944T>C p.L315P (on ENST00000355622 / NM_138554.5; = p.L275P on NM_003266.4) | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100790623; called by muse, varscan2
- TMCO4 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99616020; called by muse, mutect2, varscan2
- TMEM132D | c.731C>G p.A244G | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV101396890, COSV70610292; called by muse, mutect2, varscan2
- TMEM161B | c.1406G>T p.C469F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99680318; called by muse, mutect2, varscan2
- TMEM183A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV100923828; called by muse, mutect2, varscan2
- TMEM183A | c.775A>T p.K259* | Nonsense Mutation (SNP) | VAF 36/159 reads (23%) | catalogued as COSV100923829; called by muse, mutect2, varscan2
- TMEM200A | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as COSV51649839; called by muse, mutect2
- TMEM38B | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 114/230 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV101016240; called by muse, mutect2, varscan2
- TMPRSS15 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99517274; called by muse, mutect2
- TMPRSS15 | c.2431G>T p.G811C | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99517276; called by muse, mutect2
- TMPRSS15 | c.627C>A p.N209K | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99517277; called by muse, mutect2, varscan2
- TPRKB | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 32/156 reads (21%) | catalogued as COSV99721729; called by muse, mutect2, varscan2
- TPRX1 | c.1132G>T p.G378W | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100445564; called by muse, mutect2, varscan2
- TRIM48 | c.*1+1G>T | Splice Site (SNP) | VAF 19/110 reads (17%) | catalogued as rs750550693, COSV101338232; called by muse, mutect2, varscan2
- TRIM51 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 16/147 reads (11%) | catalogued as COSV55263947, COSV99792317; called by muse, mutect2, varscan2
- TRIM6 | c.746T>G p.L249R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99546229; called by muse, mutect2, varscan2
- TRIM65 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as rs748908103, COSV99485361; called by muse, mutect2, varscan2
- TRIP6 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99307621; called by muse, mutect2, varscan2
- TRMT1 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99456842; called by muse, mutect2, varscan2
- TRPM3 | c.3793G>A p.G1265R (on ENST00000357533 / NM_001366142.2; = p.G1120R on NM_020952.6) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs200348600, COSV62594662; called by muse, mutect2, varscan2
- TTC26 | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100570921; called by muse, mutect2, varscan2
- TTC30B | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs770025859, COSV101282776; called by muse, mutect2, varscan2
- TTN | c.89379C>A p.H29793Q (on ENST00000591111; = p.H22369Q on NM_003319.4) | Missense Mutation (SNP) | VAF 76/333 reads (23%) | PolyPhen possibly damaging (0.759); catalogued as COSV100600567, COSV60139743; called by muse, mutect2, varscan2
- TTN | c.78095C>A p.P26032Q (on ENST00000591111; = p.P18608Q on NM_003319.4) | Missense Mutation (SNP) | VAF 60/291 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV100600568, COSV60021663; called by muse, mutect2, varscan2
- TTN | c.26590C>A p.Q8864K (on ENST00000591111; = p.Q7937K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/300 reads (18%) | PolyPhen benign (0.003); catalogued as COSV100600570; called by muse, mutect2, varscan2
- TTN | c.21934G>T p.E7312* (on ENST00000591111; = p.E6385* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/113 reads (20%) | catalogued as COSV100600571; called by muse, mutect2, varscan2
- TYW1 | c.1617C>G p.D539E | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV100658504; called by muse, mutect2, varscan2
- UBA2 | c.1742C>G p.A581G | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.367); catalogued as COSV99875385; called by muse, mutect2
- UBAP2 | c.3175T>A p.Y1059N | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99602060; called by muse, mutect2
- UBL7 | c.893C>G p.S298* | Nonsense Mutation (SNP) | VAF 50/281 reads (18%) | catalogued as COSV100795362, COSV63705664; called by muse, mutect2, varscan2
- UMOD | c.1329C>A p.V443= | Splice Region (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100208121, COSV56778929; called by muse, mutect2, varscan2
- UMODL1 | c.3693T>G p.N1231K (on ENST00000408910 / NM_001004416.2; = p.N1359K on NM_173568.3) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV101252509; called by muse, varscan2
- UNC5A | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV99994307; called by muse, mutect2, varscan2
- UNC79 | c.7298C>T p.S2433F (on ENST00000393151 / NM_001346218.2; = p.S2256F on NM_020818.5) | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99826440; called by muse, mutect2, varscan2
- UPF3A | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100677546; called by muse, mutect2, varscan2
- UTRN | c.3026A>G p.H1009R | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs766506915, COSV100839720; called by muse, mutect2, varscan2
- VPS50 | c.2887A>G p.K963E | Missense Mutation (SNP) | VAF 120/265 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100004622; called by muse, mutect2, varscan2
- WAPL | c.1795C>G p.P599A | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99556355; called by muse, mutect2, varscan2
- WASHC2A | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV104391192; called by muse, mutect2
- WASHC4 | c.2789G>T p.R930I | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100162271; called by muse, mutect2, varscan2
- WDR7 | c.4298G>C p.G1433A | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1001178514, COSV99588933; called by muse, mutect2, varscan2
- WEE2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV66878619; called by muse, mutect2, varscan2
- WWC1 | c.1653G>T p.M551I | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99514530; called by muse, mutect2, varscan2
- XIRP2 | c.5939A>T p.D1980V (on ENST00000628543; = p.D2155V on NM_152381.6) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as rs751190496, COSV99740117; called by muse, mutect2, varscan2
- XIRP2 | c.10008A>T p.Q3336H (on ENST00000628543; = p.Q3511H on NM_152381.6) | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99740123; called by muse, mutect2, varscan2
- XPNPEP1 | c.1453-2A>G p.X485_splice | Splice Site (SNP) | VAF 25/95 reads (26%) | catalogued as COSV100450891; called by muse, mutect2, varscan2
- YLPM1 | c.3782G>A p.R1261Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); catalogued as rs762434022, COSV99458984; called by muse, mutect2, varscan2
- ZBTB22 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99801686; called by muse, mutect2, varscan2
- ZC3H12C | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99584715; called by muse, mutect2, varscan2
- ZFHX4 | c.5853T>A p.C1951* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as COSV99259329; called by muse, mutect2, varscan2
- ZFPM2 | c.1922G>C p.G641A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101023079; called by muse, mutect2, varscan2
- ZFYVE21 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV99157950; called by muse, mutect2, varscan2
- ZNF365 | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV101237946; called by muse, mutect2, varscan2
- ZNF365 | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV101237947, COSV101238009; called by muse, mutect2, varscan2
- ZNF423 | c.3329G>T p.G1110V (on ENST00000563137 / NM_001379286.1; = p.G1102V on NM_015069.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV52204718, COSV99280611; called by muse, mutect2, varscan2
- ZNF462 | c.6205C>G p.L2069V | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99471129; called by muse, mutect2, varscan2
- ZNF502 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99939602, COSV99939628; called by muse, mutect2, varscan2
- ZNF512B | c.311G>T p.R104M | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99411635; called by muse, mutect2, varscan2
- ZNF709 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV101172108, COSV67194776, COSV67194861; called by muse, mutect2, varscan2
- ZNF721 | c.322A>T p.K108* (on ENST00000338977; = p.K120* on NM_133474.4) | Nonsense Mutation (SNP) | VAF 25/126 reads (20%) | catalogued as COSV100167212; called by muse, mutect2, varscan2
- ZNF804A | c.2644C>A p.H882N | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100166886, COSV56454265; called by muse, mutect2, varscan2
- ZNRF4 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV99706414; called by muse, mutect2, varscan2
- ADAMTS12 | c.4741dup p.R1581Kfs*87 | Frame Shift Ins (INS) | VAF 44/299 reads (15%) | called by pindel, varscan2
- ADAMTS6 | c.1802G>T p.R601M | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASCC3 | c.366dup p.P123Sfs*10 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- AUTS2 | c.2334G>T p.K778N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- BACH2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMP3 | c.890dup p.Q298Afs*13 | Frame Shift Ins (INS) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- CACNA1B | c.1687dup p.W563Lfs*78 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- FCGBP | c.3308G>T p.G1103V | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- FCGBP | c.3307G>T p.G1103W | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGHV3-16 | c.22del p.V8Ffs*7 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- IGKV1-5 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGKV6D-41 | c.238T>A p.S80T | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ITGA11 | c.176del p.G59Afs*20 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.144_146delinsTT p.Q48Hfs*6 | Frame Shift Del (DEL) | VAF 32/123 reads (26%) | called by pindel, varscan2*
- LRRN2 | c.1844C>A p.T615N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MRC1 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 73/298 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MTMR4 | c.3210del p.F1070Lfs*4 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- NMUR2 | c.581dup p.N194Kfs*57 | Frame Shift Ins (INS) | VAF 47/218 reads (22%) | called by mutect2, pindel, varscan2
- NRXN3 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- OR12D2 | c.235del p.M79Cfs*18 | Frame Shift Del (DEL) | VAF 23/124 reads (19%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, varscan2
- RDM1 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 57/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TPTE | c.424C>A p.L142I (on ENST00000618007 / NM_199261.4; = p.L124I on NM_199259.4) | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); called by muse, mutect2
- TRAV14DV4 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TRAV21 | c.182A>T p.K61I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TRAV26-1 | c.130A>T p.I44F | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TRBV28 | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- TTN | c.76895del p.P25632Qfs*77 (on ENST00000591111; = p.P18208Qfs*77 on NM_003319.4) | Frame Shift Del (DEL) | VAF 18/157 reads (11%) | called by mutect2, pindel, varscan2
- ZNF658 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); called by mutect2, varscan2
- A2M | c.2359C>A p.R787= | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as COSV100588531; called by muse, mutect2, varscan2
- ABCA1 | c.4026G>T p.R1342= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV101036675; called by muse, mutect2, varscan2
- ABCC5 | c.705G>T p.S235= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as COSV99656596, COSV99656708; called by muse, mutect2, varscan2
- ACTN2 | c.1086C>A p.P362= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV63978549; called by muse, mutect2
- ADAD1 | c.624G>A p.K208= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV56641390, COSV99635265, COSV99636245; called by muse, mutect2, varscan2
- ADAMTS18 | c.2319C>A p.G773= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99271671; called by muse, mutect2, varscan2
- ADCY1 | c.2526G>A p.P842= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs150225572; called by mutect2, varscan2
- ADCY1 | c.2922C>A p.V974= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99811525; called by muse, mutect2, varscan2
- ADCY2 | c.1812G>A p.V604= | Silent (SNP) | VAF 71/209 reads (34%) | catalogued as COSV100602146; called by muse, mutect2, varscan2
- ADGRB3 | c.1536A>G p.E512= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV101000187; called by muse, mutect2
- ADGRG6 | c.3126G>T p.V1042= | Silent (SNP) | VAF 69/324 reads (21%) | catalogued as COSV99746320; called by muse, mutect2, varscan2
- AFP | c.918C>A p.T306= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99889825; called by muse, mutect2, varscan2
- AKR1D1 | c.570C>A p.V190= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as rs760593011; called by muse, mutect2
- AL121899.2 | c.1851C>A p.T617= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs761075728, COSV101198415; called by muse, mutect2, varscan2
- AP002512.3 | c.996C>T p.R332= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99687818; called by muse, mutect2, varscan2
- AP1M2 | c.921C>T p.A307= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1410734784, COSV99140759; called by muse, mutect2
- ARMCX3 | c.597G>A p.R199= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100362204; called by muse, mutect2, varscan2
- ASCC3 | c.5052C>T p.L1684= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100976307; called by muse, mutect2, varscan2
- ATP1A2 | c.2619C>T p.N873= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as rs150835011; called by muse, mutect2
- ATPAF2 | c.642C>G p.L214= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV58266722, COSV58267006; called by muse, mutect2, varscan2
- BAMBI | c.609C>A p.S203= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100977489; called by muse, mutect2, varscan2
- BBS2 | c.285G>T p.G95= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV99802223; called by muse, mutect2, varscan2
- BCORL1 | c.2712G>A p.K904= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99498851; called by muse, mutect2, varscan2
- CA12 | c.216G>T p.T72= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV99458010; called by muse, mutect2, varscan2
- CAMK2A | c.1347G>T p.S449= (on ENST00000348628 / NM_171825.2; = p.S460= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100651965; called by muse, mutect2, varscan2
- CCL18 | c.198C>A p.G66= | Silent (SNP) | VAF 31/134 reads (23%) | called by muse, mutect2, varscan2
- CCNI2 | c.702G>A p.R234= | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as COSV101107772; called by muse, mutect2, varscan2
- CELF4 | c.843G>A p.Q281= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100611309; called by muse, mutect2, varscan2
- CLINT1 | c.1146A>T p.P382= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs943085865, COSV99753628; called by muse, mutect2, varscan2
- CNN1 | c.123G>T p.V41= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99372256; called by muse, mutect2, varscan2
- CNTRL | c.2148T>C p.D716= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99441530; called by muse, mutect2, varscan2
- CREBZF | c.900C>T p.P300= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV99476160; called by muse, mutect2, varscan2
- CRMP1 | c.1545C>A p.P515= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100271558; called by muse, mutect2, varscan2
- CSMD1 | c.7791C>A p.G2597= (on ENST00000520002; = p.G2596= on NM_033225.6) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100145310; called by muse, mutect2, varscan2
- CUL7 | c.1014G>A p.V338= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV99538121; called by muse, mutect2, varscan2
- DACT1 | c.597G>A p.A199= | Silent (SNP) | VAF 19/205 reads (9%) | catalogued as rs181833601; called by muse, mutect2
- DCTN1 | c.2769G>T p.P923= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as rs751246549, COSV100720889, COSV62621454; called by muse, mutect2, varscan2
- DEFB129 | c.120G>T p.V40= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV99857382; called by muse, mutect2, varscan2
- DIDO1 | c.4827G>A p.P1609= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1354735760, COSV99825175; called by muse, mutect2, varscan2
- DTNA | c.1737A>T p.S579= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99311515; called by muse, mutect2, varscan2
- EDN1 | c.297C>T p.P99= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV101040309, COSV101040447; called by muse, mutect2, varscan2
- EMILIN3 | c.1488C>A p.G496= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV100182451; called by muse, mutect2, varscan2
- EML1 | c.99G>A p.E33= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV99214677; called by muse, mutect2, varscan2
- ENPP2 | c.1755G>A p.R585= (on ENST00000075322 / NM_001040092.3; = p.R637= on NM_006209.5) | Silent (SNP) | VAF 107/670 reads (16%) | catalogued as COSV99307801; called by muse, mutect2, varscan2
- FAM234A | c.702G>A p.R234= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100055559; called by muse, mutect2, varscan2
- FLG | c.7791G>A p.E2597= | Silent (SNP) | VAF 34/263 reads (13%) | catalogued as COSV100911157; called by muse, mutect2, varscan2
- FMN2 | c.1758C>A p.A586= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV100143839; called by muse, mutect2
- FMN2 | c.2244C>T p.P748= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100143840; called by muse, mutect2, varscan2
- FOXG1 | c.777G>T p.P259= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1228133511; called by muse, mutect2
- FUBP3 | c.1365A>G p.P455= | Silent (SNP) | VAF 57/203 reads (28%) | catalogued as COSV100155988; called by muse, mutect2, varscan2
- GABRA2 | c.1179G>T p.T393= | Silent (SNP) | VAF 39/316 reads (12%) | catalogued as COSV100733977, COSV62915529; called by muse, mutect2, varscan2
- GABRB1 | c.822C>A p.A274= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV99780641; called by muse, mutect2, varscan2
- GEM | c.243A>T p.I81= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99891188; called by muse, mutect2, varscan2
- GMPS | c.927C>T p.T309= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV99902972; called by muse, mutect2, varscan2
- GSPT2 | c.1725C>T p.F575= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV61213999; called by muse, mutect2
- GYS2 | c.783A>T p.I261= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV99679565; called by muse, mutect2, varscan2
- HAP1 | c.918G>T p.L306= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100169486; called by muse, mutect2
- HCRTR1 | c.1173C>A p.P391= | Silent (SNP) | VAF 41/214 reads (19%) | catalogued as COSV101035806; called by muse, mutect2, varscan2
- HOXB3 | c.1083G>T p.P361= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs768828936, COSV100290590; called by muse, mutect2, varscan2
- IGKV1-16 | c.28C>T p.L10= | Silent (SNP) | VAF 31/228 reads (14%) | catalogued as rs758361616; called by muse, mutect2
- IL10RA | c.843C>T p.I281= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV99922932; called by muse, mutect2, varscan2
- KCNG1 | c.156C>A p.P52= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100857016; called by muse, mutect2, varscan2
- KCNH1 | c.1215C>A p.I405= (on ENST00000271751 / NM_172362.3; = p.I378= on NM_002238.4) | Silent (SNP) | VAF 17/197 reads (9%) | catalogued as COSV99658037; called by muse, mutect2
- KCNH2 | c.1857C>T p.F619= | Silent (SNP) | VAF 30/141 reads (21%) | catalogued as COSV100059464, COSV100060281; called by muse, mutect2, varscan2
- KCNK10 | c.1362C>A p.T454= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as COSV100067875; called by muse, mutect2, varscan2
- KIAA0586 | c.90G>T p.P30= (on ENST00000619416 / NM_001244190.2; = p.P45= on NM_014749.5) | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99374020; called by muse, mutect2, varscan2
- KIAA1614 | c.441G>T p.L147= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1305009872, COSV100851279; called by muse, mutect2, varscan2
- KIF18A | c.1146A>T p.A382= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV99588426; called by muse, mutect2
- KIF19 | c.204C>T p.D68= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as rs557578516, COSV100738994; called by muse, mutect2
- KLK9 | c.285C>A p.P95= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV99143908; called by muse, mutect2, varscan2
- LCP1 | c.783G>A p.L261= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs1172203849, COSV100549768; called by muse, mutect2, varscan2
- LGI2 | c.1164C>A p.I388= | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as rs946654162, COSV101180787, COSV66122834; called by muse, mutect2, varscan2
- LIG4 | c.819G>A p.K273= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs369808832; called by muse, mutect2, varscan2
- LOX | c.1233C>A p.G411= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV50237130; called by muse, mutect2, varscan2
- LRP1B | c.5805C>T p.S1935= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as rs1360913605, COSV101254185; called by muse, mutect2, varscan2
- LYZL1 | c.189C>A p.A63= (on ENST00000375500; = p.A17= on NM_032517.6) | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100973609; called by muse, mutect2, varscan2
- MS4A6A | c.186G>A p.L62= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100124628; called by muse, mutect2, varscan2
- MUC17 | c.3510G>T p.T1170= | Silent (SNP) | VAF 77/569 reads (14%) | catalogued as COSV60293236; called by muse, mutect2, varscan2
- MYO7A | c.3132C>A p.T1044= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101289077; called by muse, mutect2, varscan2
- NAA25 | c.2422T>C p.L808= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99927372; called by muse, mutect2, varscan2
- NAALAD2 | c.774C>A p.L258= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs764841434, COSV100428173, COSV58961859; called by muse, mutect2, varscan2
- NOTCH4 | c.1440C>T p.L480= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100900488; called by muse, mutect2, varscan2
- OR10Q1 | c.426C>T p.R142= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV57469838; called by muse, varscan2
- OR10S1 | c.393C>A p.V131= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV101602453; called by muse, mutect2, varscan2
- OR13C9 | c.343C>T p.L115= | Silent (SNP) | VAF 35/193 reads (18%) | catalogued as COSV99403375; called by muse, mutect2, varscan2
- OR1A1 | c.285G>T p.G95= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as COSV100410733; called by muse, mutect2, varscan2
- OR4D9 | c.69G>T p.L23= | Silent (SNP) | VAF 44/241 reads (18%) | catalogued as COSV100259745; called by muse, mutect2, varscan2
- OR51T1 | c.612T>A p.L204= | Silent (SNP) | VAF 11/134 reads (8%) | catalogued as COSV100434336; called by muse, mutect2
- OR5M10 | c.684C>A p.I228= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV101595866; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2493C>T p.A831= (on ENST00000259318 / NM_001136562.3; = p.A1075= on NM_007203.5) | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as COSV99394876; called by muse, mutect2, varscan2
- PCDH18 | c.2070A>T p.S690= | Silent (SNP) | VAF 69/252 reads (27%) | catalogued as COSV61267594; called by muse, mutect2, varscan2
- PLA2G4D | c.732G>T p.L244= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV99299395; called by muse, mutect2, varscan2
- PLXNC1 | c.801C>T p.I267= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV51577031, COSV51578193, COSV99312649; called by muse, mutect2
- PPM1M | c.717G>A p.R239= (on ENST00000296487; = p.R400= on NM_144641.4) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99626095; called by muse, mutect2, varscan2
- PPP6C | c.306A>G p.K102= | Silent (SNP) | VAF 11/362 reads (3%) | catalogued as rs1218917748, COSV65206925; called by muse, mutect2
- PRAMEF18 | c.714C>T p.F238= | Silent (SNP) | VAF 42/562 reads (7%) | catalogued as rs752123611; called by muse, mutect2
- PRKD1 | c.903C>T p.C301= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100119553; called by muse, mutect2, varscan2
- PRKDC | c.8763C>T p.L2921= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100039102; called by muse, mutect2, varscan2
- PTN | c.246C>T p.T82= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV100780810, COSV61966170; called by muse, mutect2, varscan2
- RBBP8 | c.2325G>C p.A775= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100507175; called by muse, mutect2, varscan2
- RBM15 | c.2818C>T p.L940= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV100873411; called by muse, mutect2, varscan2
- RC3H2 | c.2031G>T p.P677= | Silent (SNP) | VAF 60/259 reads (23%) | catalogued as COSV100605385, COSV61802129; called by muse, mutect2, varscan2
- REV3L | c.8367G>A p.L2789= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100725025; called by muse, mutect2, varscan2
- RFX6 | c.489G>C p.A163= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100263468, COSV60584519; called by muse, mutect2, varscan2
- RFX6 | c.2004G>T p.V668= | Silent (SNP) | VAF 36/202 reads (18%) | catalogued as COSV100263469, COSV100263562; called by muse, mutect2, varscan2
- RPAP3 | c.471A>C p.T157= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV99139306; called by muse, mutect2, varscan2
- RYR3 | c.9309C>A p.I3103= (on ENST00000389232; = p.I3104= on NM_001036.6) | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV101212212; called by muse, mutect2
- SLAMF6 | c.405T>A p.V135= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100924853; called by muse, varscan2
- SLC12A9 | c.210G>C p.L70= | Silent (SNP) | VAF 29/242 reads (12%) | catalogued as COSV99307617; called by muse, mutect2, varscan2
- SLC17A6 | c.1380T>C p.C460= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV99581036; called by muse, mutect2, varscan2
- SLC52A3 | c.480C>T p.G160= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV99447700; called by muse, mutect2, varscan2
- SLC9A3 | c.1344C>A p.T448= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as COSV99375763; called by muse, mutect2, varscan2
- SORCS1 | c.2412G>T p.T804= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as rs375256122, COSV53865106, COSV99544316; called by muse, mutect2, varscan2
- SP4 | c.1296G>T p.T432= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as rs1163535773, COSV99754187; called by muse, mutect2, varscan2
- SPEG | c.3801C>A p.G1267= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV100403697; called by muse, mutect2, varscan2
- SSU72P8 | c.514C>T p.L172= | Silent (SNP) | VAF 68/114 reads (60%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.768G>T p.P256= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs545732586, COSV99185157; called by muse, mutect2, varscan2
- STIL | c.114A>T p.P38= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV99680725; called by muse, mutect2, varscan2
- STRIP2 | c.348A>T p.L116= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99973578; called by muse, mutect2, varscan2
- STRIP2 | c.1191G>C p.L397= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs747858494, COSV99973581; called by muse, mutect2, varscan2
- SUMO1 | c.186C>G p.L62= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV101108602; called by muse, mutect2, varscan2
- SYNE1 | c.189G>T p.L63= | Silent (SNP) | VAF 18/147 reads (12%) | catalogued as COSV99556957; called by muse, mutect2, varscan2
- TANC2 | c.3498C>T p.G1166= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV101267292; called by muse, mutect2, varscan2
- TEX15 | c.5520G>T p.G1840= (on ENST00000256246; = p.G2223= on NM_001350162.2) | Silent (SNP) | VAF 44/166 reads (27%) | catalogued as COSV99820957; called by muse, mutect2, varscan2
- TIAM1 | c.201C>T p.S67= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs745446921, COSV54547658, COSV54561556; called by muse, mutect2, varscan2
- TM9SF4 | c.1092A>T p.V364= | Silent (SNP) | VAF 53/218 reads (24%) | catalogued as COSV99454142; called by muse, mutect2, varscan2
- TRIM3 | c.1476G>T p.V492= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100624288; called by muse, mutect2, varscan2
- TRPC5 | c.186C>T p.N62= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs762529573, COSV99459835; called by muse, mutect2, varscan2
- TSPAN33 | c.834G>T p.R278= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99179722; called by muse, mutect2, varscan2
- TTN | c.21594C>A p.P7198= (on ENST00000591111; = p.P6271= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/248 reads (15%) | catalogued as COSV60153327; called by muse, mutect2, varscan2
- UBA2 | c.1908C>A p.V636= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV99875386; called by muse, mutect2, varscan2
- UGT3A2 | c.30G>T p.V10= | Silent (SNP) | VAF 39/268 reads (15%) | catalogued as COSV99236103; called by muse, mutect2, varscan2
- VWF | c.6399C>A p.V2133= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99778433; called by muse, mutect2, varscan2
- WDR25 | c.1419G>A p.E473= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100091485; called by muse, mutect2, varscan2
- WRNIP1 | c.1425G>A p.L475= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV101062700; called by muse, mutect2, varscan2
- XIRP2 | c.3438C>A p.L1146= (on ENST00000628543; = p.L1321= on NM_152381.6) | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV99740114; called by muse, mutect2, varscan2
- XIRP2 | c.8436G>A p.L2812= (on ENST00000628543; = p.L2987= on NM_152381.6) | Silent (SNP) | VAF 34/205 reads (17%) | catalogued as COSV54709527, COSV99747742; called by muse, mutect2, varscan2
- ZNF202 | c.1866G>T p.T622= | Silent (SNP) | VAF 25/184 reads (14%) | catalogued as COSV100278960, COSV60246894; called by muse, mutect2, varscan2
- ZNF366 | c.135G>T p.P45= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100574148, COSV100574316; called by muse, mutect2, varscan2
- ZNF410 | c.993G>A p.V331= | Silent (SNP) | VAF 41/269 reads (15%) | catalogued as COSV100206309; called by muse, mutect2, varscan2
- ZNF526 | c.615C>G p.L205= | Silent (SNP) | VAF 55/218 reads (25%) | catalogued as COSV56629804; called by muse, mutect2, varscan2
- ZNF536 | c.2685C>T p.T895= | Silent (SNP) | VAF 52/272 reads (19%) | catalogued as COSV100834883; called by muse, mutect2, varscan2
- ZNF615 | c.102G>T p.R34= | Silent (SNP) | VAF 72/230 reads (31%) | catalogued as COSV100943736; called by muse, mutect2, varscan2
- ZYG11B | c.253C>A p.R85= | Silent (SNP) | VAF 23/195 reads (12%) | catalogued as COSV53753316, COSV99597008; called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-481-1933G>T | Intron (SNP) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- CIT | c.4729-448T>G | Intron (SNP) | VAF 24/141 reads (17%) | called by muse, mutect2, varscan2
- FCRL2 | c.884-40C>A | Intron (SNP) | VAF 32/133 reads (24%) | catalogued as rs149880764, COSV100829848; called by muse, mutect2, varscan2
- HMGB1P1 | n.76G>T | RNA (SNP) | VAF 89/274 reads (32%) | catalogued as rs1461052598; called by muse, mutect2, varscan2
- MIR216A | n.93A>G | RNA (SNP) | VAF 44/309 reads (14%) | catalogued as rs763149314; called by muse, mutect2, varscan2
- MYADM | chr19:53874388 G>C | 3'Flank (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100424981, COSV61240542; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 16/51 reads (31%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- ZNF99 | c.*39G>T | 3'UTR (SNP) | VAF 19/85 reads (22%) | catalogued as COSV101233754; called by muse, mutect2, varscan2
